Somatic mutation profile of tumor specimen HCM-WCMC-0673-C56-05A (aliquot HCM-WCMC-0673-C56-05A-25D-A85C-36) from HCMI case HCM-WCMC-0673-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Ovary; AJCC pathologic stage: Stage IIIA2; FIGO stage: Stage III; Age at diagnosis: 32.9 years (12,015 days).
Specimen HCM-WCMC-0673-C56-05A: Sample type: Slides; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9aff354c-d642-4f44-a5a2-739d86c73fe3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-WCMC-0673-C56-10A (Blood Derived Normal), aliquot HCM-WCMC-0673-C56-10A-01D-A85C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d3ad7cc2-98c1-4f18-adb6-b80c7507ad40

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMAD4 | c.1157G>A p.G386D | Missense Mutation (SNP) | VAF 36/488 reads (7%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs121912580, CM021284, COSV61684421, COSV61688134, COSV61692671; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- AIFM2 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 24/486 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as rs750119679, COSV100325838; called by muse, mutect2
- METTL8 | c.311G>A p.R104H | Missense Mutation (SNP) | VAF 40/522 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs754629409; called by muse, mutect2
- ULK3 | c.625G>A p.G209R | Missense Mutation (SNP) | VAF 20/566 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1018512142; called by muse, mutect2
- LARS1 | c.1284+1G>T p.X428_splice (on ENST00000394434 / NM_020117.11; = p.X401_splice on NM_016460.3) | Splice Site (SNP) | VAF 16/388 reads (4%) | called by muse, mutect2
- PRSS54 | c.1030G>C p.G344R | Missense Mutation (SNP) | VAF 35/726 reads (5%) | SIFT tolerated (0.2); PolyPhen benign (0.015); called by muse, mutect2
- FUT9 | c.*7911A>G | 3'UTR (SNP) | VAF 26/542 reads (5%) | catalogued as COSV100133553; called by muse, mutect2
